Gene-level copy-number profile of tumor specimen ALCH-B3H0-TTP1-A from ALCHEMIST case ALCH-B3H0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.2 years (27,845 days).
Specimen ALCH-B3H0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9c0b70e-1710-4e9e-b1f5-93908994edca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3H0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/7b60d9aa-e227-45ef-aebe-cb1360b974e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 497; copy number 1: 13,168; copy number 2: 40,755; copy number 3: 4,450; copy number 4: 5; copy number 5: 3; copy number 7: 7; copy number 8: 1; copy number 9: 6; copy number 10: 2; copy number 11: 1; copy number 24: 2.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes: AC239859.5, RNA5SP533, AC239859.3.
- chr2:237,563,165–237,563,270, 1 gene: RNU6-1140P.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:4,012,708–4,013,649, 1 gene: AC025773.1.
- chr11:60,785,333–60,801,305, 1 gene: MS4A10.
- chr12:47,972,967–48,004,554, 1 gene: COL2A1.
- chr14:100,814,491–100,816,244, 2 genes (within-gene range 0–2): MIR2392, AL117190.5.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.
- chr15:25,176,832–25,243,695, 36 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr16:54,239,693–54,240,654, 1 gene: AC007907.1.
- chr17:17,578,631–17,578,739, 1 gene (within-gene range 0–2): RNU6-468P.
- chr17:63,819,433–63,843,065, 3 genes: FTSJ3, PSMC5, SMARCD2.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–2): AC090386.2.
- chr21:17,296,219–17,296,596, 1 gene: AP000457.1.
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 10: AC239859.2, LINC02799.
- chr21:43,414,483–43,427,131, 1 gene, copy number 11: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 7: LINC00313, AP001048.1.
- chr22:18,361,820–18,530,573, 9 genes, copy number 7–9: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, TMEM191B.
- chr22:18,636,445–18,653,617, 2 genes, copy number 5: CA15P2, PPP1R26P2.
- chr22:18,733,914–18,843,399, 3 genes, copy number 7–8 (within-gene range 1–11): FAM230E, GGT3P, AC008132.2.
- chr22:18,873,543–18,894,407, 2 genes, copy number 24: FAM230F, AC008103.1.
- chr22:24,269,346–24,270,134, 1 gene, copy number 5: AP000354.1.

Autosomal genes at a single copy (total copy number 1): 11,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
